Somatic mutation profile of tumor specimen C3L-08974-01 (aliquot CPT0498110006) from CPTAC case C3L-08974, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 81.7 years (29,859 days).
Specimen C3L-08974-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 099256bc-b299-4d1e-9e25-7bec54f2e9ae.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-08974-32 (Blood Derived Normal), aliquot CPT0498260001; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8de19bc8-6aab-476f-980f-58fa6718467c

The open-access MAF lists 35 somatic variants for this specimen: 23 protein-altering or splice-affecting, 8 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 8, Intron 4, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC011005.1 | c.193G>A p.E65K | Missense Mutation (SNP) | VAF 24/527 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV71955940; called by muse, mutect2
- CACNA1E | c.4059C>A p.F1353L | Missense Mutation (SNP) | VAF 46/464 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62391265; called by muse, mutect2
- CSMD1 | c.5290G>A p.V1764I (on ENST00000520002; = p.V1763I on NM_033225.6) | Missense Mutation (SNP) | VAF 205/608 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.025); catalogued as rs752235970, COSV59344777; called by muse, mutect2, varscan2
- GDF10 | c.874G>A p.A292T | Missense Mutation (SNP) | VAF 22/669 reads (3%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as rs782131518; called by muse, mutect2
- GRIN3A | c.199C>T p.R67C | Missense Mutation (SNP) | VAF 21/743 reads (3%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.251); catalogued as COSV62457324; called by muse, mutect2
- IGSF8 | c.1582C>T p.R528W | Missense Mutation (SNP) | VAF 35/656 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs749014923; called by muse, mutect2
- ILDR2 | c.1156C>T p.R386C | Missense Mutation (SNP) | VAF 36/402 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); catalogued as rs768427799; called by muse, mutect2
- NOVA1 | c.832G>C p.V278L | Missense Mutation (SNP) | VAF 10/330 reads (3%) | SIFT tolerated (0.43); PolyPhen benign (0.031); catalogued as rs1258354651; called by muse, mutect2
- PHKA2 | c.1384G>A p.V462I | Missense Mutation (SNP) | VAF 14/366 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.063); catalogued as rs1389980232, COSV66053427; called by muse, mutect2
- SLC4A1AP | c.1306C>T p.R436W | Missense Mutation (SNP) | VAF 29/323 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762989146; called by muse, mutect2
- AMER2 | c.427A>G p.R143G | Missense Mutation (SNP) | VAF 22/549 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2
- CAND2 | c.1442-1G>A p.X481_splice (on ENST00000456430 / NM_001162499.2; = p.X388_splice on NM_012298.3) | Splice Site (SNP) | VAF 10/328 reads (3%) | called by muse, mutect2
- CLEC14A | c.139C>T p.R47W | Missense Mutation (SNP) | VAF 22/786 reads (3%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.973); called by muse, mutect2
- CLEC17A | c.1005C>T p.S335= (on ENST00000417570 / NM_001204118.2; = p.L299F on NM_207390.3) | Splice Region (SNP) | VAF 11/250 reads (4%) | called by muse, mutect2
- CNOT3 | c.1502C>T p.P501L | Missense Mutation (SNP) | VAF 30/798 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.027); called by muse, mutect2
- ERVMER34-1 | c.1606C>T p.L536F | Missense Mutation (SNP) | VAF 21/340 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); called by muse, mutect2
- FAM13C | c.560A>C p.Q187P | Missense Mutation (SNP) | VAF 12/434 reads (3%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2
- MTMR7 | c.161A>C p.Q54P | Missense Mutation (SNP) | VAF 13/286 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.078); called by muse, mutect2
- OR2T34 | c.517T>C p.F173L | Missense Mutation (SNP) | VAF 28/586 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); called by muse, mutect2
- RANBP6 | c.982G>A p.D328N | Missense Mutation (SNP) | VAF 14/328 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.033); called by muse, mutect2
- SCYL3 | c.2129T>C p.M710T (on ENST00000367770; = p.M656T on NM_020423.7) | Missense Mutation (SNP) | VAF 17/220 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, mutect2
- TENM4 | c.5977A>C p.T1993P | Missense Mutation (SNP) | VAF 13/406 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.073); called by muse, mutect2
- USP6 | c.104G>A p.G35E | Missense Mutation (SNP) | VAF 13/260 reads (5%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.931); called by muse, mutect2
- ARCN1 | c.141G>A p.T47= | Silent (SNP) | VAF 13/326 reads (4%) | catalogued as rs781824770; called by muse, mutect2
- ATP2B4 | c.2688G>A p.T896= | Silent (SNP) | VAF 34/554 reads (6%) | catalogued as rs200415493, COSV58181086; called by muse, mutect2
- COX15 | c.420A>T p.T140= | Silent (SNP) | VAF 11/273 reads (4%) | called by muse, mutect2
- EVA1A | c.123C>T p.G41= | Silent (SNP) | VAF 28/367 reads (8%) | catalogued as rs1286070717; called by muse, mutect2
- FAM47A | c.825C>T p.D275= | Silent (SNP) | VAF 19/582 reads (3%) | catalogued as COSV60494645; called by muse, mutect2
- LRRC32 | c.46C>T p.L16= | Silent (SNP) | VAF 12/360 reads (3%) | catalogued as COSV99477367; called by muse, mutect2
- PCDHA9 | c.1365C>T p.F455= | Silent (SNP) | VAF 28/696 reads (4%) | catalogued as rs1451585591, COSV65331143; called by muse, mutect2
- TGFBI | c.1077C>T p.A359= | Silent (SNP) | VAF 14/307 reads (5%) | called by muse, mutect2
- GAPVD1 | c.2429-1770T>A | Intron (SNP) | VAF 13/203 reads (6%) | called by muse, mutect2
- MEX3B | c.256+102G>T | Intron (SNP) | VAF 18/514 reads (4%) | called by muse, mutect2
- PRR12 | c.52-49C>T | Intron (SNP) | VAF 18/574 reads (3%) | catalogued as rs1460474511; called by muse, mutect2
- ST6GAL2 | c.1319-6225C>T | Intron (SNP) | VAF 14/278 reads (5%) | catalogued as rs1271761670, COSV62418177; called by muse, mutect2
